Somatic mutation profile of tumor specimen TCGA-04-1360-01A (aliquot TCGA-04-1360-01A-01W-0492-08) from TCGA case TCGA-04-1360, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 65.7 years (23,993 days).
Specimen TCGA-04-1360-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4c792949-1933-4843-a65b-80397f315396.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-04-1360-11A (Solid Tissue Normal), aliquot TCGA-04-1360-11A-01W-0492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/434bd7d8-91fb-44f5-8e1e-975963a6b733

The open-access MAF lists 118 somatic variants for this specimen: 91 protein-altering or splice-affecting, 24 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 83, Silent 24, Frame Shift Del 3, Intron 2, Nonsense Mutation 2, Splice Site 1, Splice Region 1, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.527G>T p.C176F | Missense Mutation (SNP) | VAF 236/340 reads (69%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABL2 | c.1691C>T p.S564F (on ENST00000502732 / NM_007314.4; = p.S549F on NM_005158.5) | Missense Mutation (SNP) | VAF 190/973 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.284); catalogued as COSV100772970; called by muse, varscan2
- ADK | c.239G>C p.G80A (on ENST00000286621; = p.G63A on NM_001123.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV99693421; called by muse, mutect2, varscan2
- AGGF1 | c.2124G>C p.W708C | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100462230; called by muse, mutect2
- AKR1B10 | c.851A>G p.E284G | Missense Mutation (SNP) | VAF 279/544 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.326); catalogued as COSV100610252; called by muse, varscan2
- APEH | c.1386C>G p.H462Q | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV99611120; called by muse, mutect2, varscan2
- ARHGAP28 | c.2064C>A p.N688K (on ENST00000383472 / NM_001366230.1; = p.N529K on NM_001010000.3) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.47); PolyPhen benign (0.014); catalogued as COSV100060856; called by muse, varscan2
- ARMC8 | c.808C>G p.R270G (on ENST00000469044 / NM_001363941.2; = p.R256G on NM_014154.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.017); catalogued as COSV100627866; called by muse, mutect2
- ARNT2 | c.1924A>G p.S642G | Missense Mutation (SNP) | VAF 26/531 reads (5%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs745512981, COSV100309542; called by muse, mutect2
- ATP4A | c.126G>C p.K42N | Missense Mutation (SNP) | VAF 41/282 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.025); catalogued as COSV99383073; called by muse, mutect2, varscan2
- BCAS3 | c.1334C>T p.T445I | Missense Mutation (SNP) | VAF 58/284 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101177063; called by muse, mutect2, varscan2
- BSDC1 | c.1221G>T p.E407D | Missense Mutation (SNP) | VAF 35/182 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV100345068; called by muse, mutect2, varscan2
- C5AR1 | c.578G>A p.S193N | Missense Mutation (SNP) | VAF 147/531 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV100754067; called by muse, varscan2
- CCN1 | c.1025C>T p.T342I | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.015); catalogued as COSV101486143; called by muse, mutect2, varscan2
- CD44 | c.989G>T p.S330I | Missense Mutation (SNP) | VAF 32/689 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.36); catalogued as rs751411160, COSV99555998; called by muse, mutect2
- CDCA3 | c.434C>G p.P145R | Missense Mutation (SNP) | VAF 12/149 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.238); catalogued as COSV99977112; called by muse, mutect2
- CDK5RAP1 | c.1415T>A p.F472Y (on ENST00000357886 / NM_001365728.1; = p.F458Y on NM_016082.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 86/1004 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as COSV100212287; called by muse, mutect2
- CDKN2C | c.374A>C p.H125P | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.754); catalogued as COSV99396051; called by muse, mutect2, varscan2
- CEACAM5 | c.787T>A p.S263T | Missense Mutation (SNP) | VAF 198/734 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.92); catalogued as COSV99704157; called by muse, mutect2, varscan2
- CELF6 | c.1157C>A p.P386H | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV99764159; called by muse, mutect2, varscan2
- COL4A2 | c.3715G>A p.G1239S | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100847477; called by muse, mutect2, varscan2
- COL6A3 | c.1043A>T p.Q348L | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99801329; called by muse, mutect2, varscan2
- CP | c.2662-2A>G p.X888_splice | Splice Site (SNP) | VAF 18/395 reads (5%) | catalogued as COSV99224460; called by muse, mutect2
- CSMD2 | c.3907G>A p.E1303K | Missense Mutation (SNP) | VAF 48/766 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs756045595, COSV99592111; called by muse, mutect2
- CYC1 | c.806A>G p.D269G | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100010606; called by muse, mutect2, varscan2
- DDX58 | c.1038A>T p.L346F | Missense Mutation (SNP) | VAF 63/217 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.869); catalogued as COSV101153233; called by muse, mutect2, varscan2
- EPHA1 | c.2752G>A p.V918I | Missense Mutation (SNP) | VAF 36/530 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as rs530042951, COSV51969852, COSV99314669; called by muse, mutect2
- FASTKD1 | c.2382G>A p.M794I | Missense Mutation (SNP) | VAF 37/358 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV99500605; called by muse, mutect2
- FRY | c.4585G>C p.A1529P | Missense Mutation (SNP) | VAF 158/378 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV100969894; called by muse, mutect2, varscan2
- HAPLN4 | c.403C>A p.L135M | Missense Mutation (SNP) | VAF 56/551 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.93); catalogued as COSV99364023; called by muse, mutect2, varscan2
- HARS1 | c.1414A>C p.K472Q | Missense Mutation (SNP) | VAF 26/296 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.271); catalogued as COSV100298299; called by muse, mutect2
- HECTD1 | c.4245T>G p.S1415R | Missense Mutation (SNP) | VAF 18/455 reads (4%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV101237510; called by muse, mutect2
- IBTK | c.340A>T p.I114F | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as COSV100091470, COSV60392690; called by muse, mutect2, varscan2
- IRGC | c.1060G>A p.A354T | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.978); catalogued as rs761525743, COSV99746540; called by muse, mutect2, varscan2
- LAMC2 | c.442G>C p.G148R | Missense Mutation (SNP) | VAF 106/272 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as COSV99917946; called by muse, mutect2, varscan2
- LILRB5 | c.1534A>C p.K512Q (on ENST00000449561 / NM_001081442.3; = p.K511Q on NM_006840.5) | Missense Mutation (SNP) | VAF 49/142 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as COSV100300799; called by muse, mutect2, varscan2
- LRRC4B | c.299T>C p.V100A | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.33); PolyPhen benign (0.059); catalogued as COSV100976045; called by muse, mutect2, varscan2
- MCC | c.1641C>A p.T547= | Splice Region (SNP) | VAF 41/195 reads (21%) | catalogued as COSV100203183; called by muse, mutect2, varscan2
- MOV10L1 | c.2579T>A p.I860N | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV99435105; called by muse, mutect2, varscan2
- MUC3A | c.8842C>A p.Q2948K | Missense Mutation (SNP) | VAF 42/1092 reads (4%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.376); catalogued as COSV100115362, COSV60212839; called by muse, mutect2
- MYH7 | c.1331A>G p.N444S | Missense Mutation (SNP) | VAF 348/828 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs730880159, CM111026, COSV100806625; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- NEB | c.2455A>G p.K819E | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.992); catalogued as COSV99427835; called by muse, mutect2
- NETO1 | c.1154A>T p.Q385L | Missense Mutation (SNP) | VAF 200/935 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV100199717; called by muse, mutect2, varscan2
- NPTX1 | c.665A>G p.N222S | Missense Mutation (SNP) | VAF 26/40 reads (65%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs527543428, COSV100151188; called by muse, mutect2, varscan2
- NTRK2 | c.417C>A p.D139E | Missense Mutation (SNP) | VAF 129/262 reads (49%) | SIFT tolerated (0.5); PolyPhen benign (0.109); catalogued as COSV99458464; called by muse, mutect2, varscan2
- OBSCN | c.17899C>T p.R5967C | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs919675899, COSV52785484; called by muse, mutect2, varscan2
- ONECUT1 | c.1170G>T p.L390F | Missense Mutation (SNP) | VAF 183/510 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100009428; called by muse, mutect2, varscan2
- OR2B2 | c.578C>G p.T193R | Missense Mutation (SNP) | VAF 154/397 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as rs774501936, COSV100308232; called by muse, mutect2, varscan2
- OR2T11 | c.232C>T p.L78F | Missense Mutation (SNP) | VAF 64/333 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV100424958; called by muse, mutect2, varscan2
- OR5AC2 | c.398T>C p.L133P | Missense Mutation (SNP) | VAF 132/717 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100684488; called by muse, mutect2, varscan2
- OR6S1 | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 81/210 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148281603, COSV100289522; called by muse, mutect2, varscan2
- PCDHGA4 | c.115C>G p.P39A | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.014); catalogued as rs1451829611; called by mutect2, varscan2
- PDK4 | c.715A>G p.I239V | Missense Mutation (SNP) | VAF 60/99 reads (61%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs755170552, COSV99138968; called by muse, mutect2, varscan2
- PIGR | c.434G>A p.G145D | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.738); catalogued as rs1349069697, COSV100732562, COSV100732703; called by muse, mutect2, varscan2
- PPM1B | c.909T>A p.D303E | Missense Mutation (SNP) | VAF 34/289 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99175905; called by muse, mutect2, varscan2
- PRKCG | c.1304A>G p.E435G | Missense Mutation (SNP) | VAF 85/265 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV54732382; called by muse, mutect2, varscan2
- PRXL2B | c.571C>G p.L191V (on ENST00000444521; = p.L143V on NM_152371.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.72); catalogued as COSV99984450; called by muse, mutect2, varscan2
- PTPN6 | c.758A>T p.K253M | Missense Mutation (SNP) | VAF 32/280 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.53); catalogued as COSV100017277, COSV59683537; called by muse, varscan2
- PXDNL | c.2500T>C p.S834P | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.516); catalogued as COSV100686196; called by muse, mutect2, varscan2
- RBBP9 | c.286G>A p.V96M | Missense Mutation (SNP) | VAF 20/338 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100464182; called by muse, mutect2
- RBL1 | c.2662C>G p.P888A | Missense Mutation (SNP) | VAF 67/163 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV100727287; called by muse, mutect2, varscan2
- RBP5 | c.149T>A p.M50K | Missense Mutation (SNP) | VAF 154/927 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.194); catalogued as COSV99867679; called by muse, mutect2, varscan2
- RHOU | c.482C>T p.T161M | Missense Mutation (SNP) | VAF 124/246 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs182348025; called by muse, mutect2, varscan2
- S1PR1 | c.1020C>A p.F340L | Missense Mutation (SNP) | VAF 40/456 reads (9%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV100541674, COSV59514165; called by muse, mutect2
- SIGLEC1 | c.3673C>T p.R1225C | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1174592885, COSV99170772; called by muse, varscan2
- SLC25A39 | c.701G>A p.W234* (on ENST00000377095 / NM_001143780.3; = p.W226* on NM_016016.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 22/132 reads (17%) | catalogued as COSV99835413; called by muse, mutect2, varscan2
- SLC4A9 | c.945C>G p.F315L (on ENST00000507527 / NM_001258428.2; = p.F291L on NM_031467.3) | Missense Mutation (SNP) | VAF 35/174 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99139826; called by muse, mutect2, varscan2
- SLF2 | c.1829A>G p.Y610C | Missense Mutation (SNP) | VAF 78/149 reads (52%) | SIFT tolerated (0.72); PolyPhen benign (0.023); catalogued as COSV99489726; called by muse, mutect2, varscan2
- SMARCD2 | c.1552C>T p.R518* | Nonsense Mutation (SNP) | VAF 9/52 reads (17%) | catalogued as rs79899871, COSV99856643; called by muse, mutect2, varscan2
- SRL | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.704); catalogued as rs1298880867, COSV68422797; called by muse, mutect2, varscan2
- STK4 | c.1109T>A p.I370N | Missense Mutation (SNP) | VAF 37/1004 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV100860461; called by muse, mutect2
- SULT1B1 | c.158G>C p.W53S | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100150484; called by muse, mutect2, varscan2
- SYNJ2BP | c.287T>C p.V96A | Missense Mutation (SNP) | VAF 176/662 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV99832723; called by muse, mutect2, varscan2
- TACC2 | c.6803A>T p.D2268V (on ENST00000334433; = p.D346V on NM_006997.4) | Missense Mutation (SNP) | VAF 228/357 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99587699; called by mutect2, varscan2
- TAOK3 | c.555G>A p.M185I | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV101183789; called by muse, varscan2
- TDRD1 | c.187A>G p.K63E | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as COSV99315107; called by muse, mutect2
- THG1L | c.323G>C p.S108T | Missense Mutation (SNP) | VAF 81/264 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99180288; called by muse, mutect2, varscan2
- TMEM59L | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.89); PolyPhen benign (0.031); catalogued as COSV99450517; called by muse, mutect2, varscan2
- TMPRSS15 | c.2048G>C p.G683A | Missense Mutation (SNP) | VAF 49/176 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV99519251; called by muse, mutect2, varscan2
- TNFRSF10B | c.535G>T p.V179F | Missense Mutation (SNP) | VAF 78/438 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.431); catalogued as COSV99375622; called by muse, mutect2, varscan2
- TRARG1 | c.355C>G p.L119V | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.75); PolyPhen benign (0.306); catalogued as COSV100416956; called by muse, mutect2, varscan2
- USP53 | c.748G>T p.V250F | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99918048; called by muse, mutect2, varscan2
- WDFY3 | c.8783T>C p.V2928A | Missense Mutation (SNP) | VAF 173/266 reads (65%) | SIFT tolerated (0.05); PolyPhen benign (0.212); catalogued as COSV99885603; called by muse, mutect2, varscan2
- ZNF202 | c.1883A>T p.K628I | Missense Mutation (SNP) | VAF 46/211 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as COSV100279150; called by muse, mutect2, varscan2
- ZNF493 | c.1563A>C p.Q521H | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100828923; called by muse, mutect2, varscan2
- DNAH8 | c.11841_11848del p.H3947Qfs*36 | Frame Shift Del (DEL) | VAF 69/590 reads (12%) | called by mutect2, pindel, varscan2
- FCGBP | c.962G>A p.G321D | Missense Mutation (SNP) | VAF 49/251 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLEKHH2 | c.2839del p.I947Yfs*18 | Frame Shift Del (DEL) | VAF 57/140 reads (41%) | called by mutect2, pindel, varscan2
- RABL2B | c.192_200del p.V65_G67del | In Frame Del (DEL) | VAF 24/199 reads (12%) | called by mutect2, pindel, varscan2
- TBC1D10A | c.967del p.A323Pfs*34 | Frame Shift Del (DEL) | VAF 16/35 reads (46%) | called by mutect2, pindel, varscan2
- TIMM23 | c.542G>T p.G181V | Missense Mutation (SNP) | VAF 61/394 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- AL121899.2 | c.1749G>T p.L583= | Silent (SNP) | VAF 58/1078 reads (5%) | catalogued as COSV101198681; called by muse, mutect2
- AP1M2 | c.747C>T p.N249= | Silent (SNP) | VAF 13/126 reads (10%) | catalogued as rs368763595; called by muse, mutect2, varscan2
- ATF7IP | c.3423C>T p.P1141= | Silent (SNP) | VAF 23/285 reads (8%) | catalogued as COSV99662116; called by muse, mutect2
- ATP4A | c.127C>T p.L43= | Silent (SNP) | VAF 41/280 reads (15%) | catalogued as COSV99383067; called by muse, mutect2, varscan2
- C5 | c.1431A>T p.L477= | Silent (SNP) | VAF 40/48 reads (83%) | catalogued as COSV99798693; called by muse, mutect2, varscan2
- CHD2 | c.1617C>T p.V539= | Silent (SNP) | VAF 61/413 reads (15%) | catalogued as COSV101245969; called by muse, mutect2, varscan2
- CSAD | c.324T>C p.T108= (on ENST00000444623 / NM_001244705.2; = p.T135= on NM_015989.5) | Silent (SNP) | VAF 46/131 reads (35%) | catalogued as COSV57245018; called by muse, mutect2, varscan2
- DDX42 | c.2265C>A p.P755= | Silent (SNP) | VAF 262/329 reads (80%) | catalogued as COSV100835068; called by muse, mutect2, varscan2
- DGKZ | c.1344G>A p.K448= (on ENST00000454345 / NM_001105540.2; = p.K260= on NM_003646.4) | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV100551954; called by muse, mutect2, varscan2
- EML2 | c.1440C>T p.H480= | Silent (SNP) | VAF 108/227 reads (48%) | catalogued as COSV99840443; called by muse, mutect2, varscan2
- FAT4 | c.6747A>G p.L2249= | Silent (SNP) | VAF 304/415 reads (73%) | catalogued as rs370316723, COSV100630098; called by muse, mutect2, varscan2
- GDF15 | c.387G>T p.P129= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as COSV99416304; called by muse, mutect2
- GJB1 | c.414C>T p.S138= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as rs1317916250, COSV100661306; ClinVar: likely benign; called by muse, mutect2, varscan2
- HEPH | c.255A>T p.S85= (on ENST00000343002; = p.S139= on NM_138737.5) | Silent (SNP) | VAF 133/277 reads (48%) | catalogued as COSV100295685; called by muse, mutect2, varscan2
- HOXA11 | c.816G>T p.L272= | Silent (SNP) | VAF 19/98 reads (19%) | catalogued as COSV99136123; called by muse, mutect2, varscan2
- NEMP1 | c.1329A>T p.L443= (on ENST00000300128 / NM_001130963.2; = p.L370= on NM_015257.3) | Silent (SNP) | VAF 53/157 reads (34%) | catalogued as COSV100272299; called by muse, mutect2, varscan2
- NIT1 | c.600A>C p.L200= | Silent (SNP) | VAF 21/176 reads (12%) | catalogued as COSV100919136; called by muse, mutect2, varscan2
- PDXDC1 | c.2253A>C p.G751= | Silent (SNP) | VAF 34/91 reads (37%) | catalogued as rs139557508; called by muse, mutect2, varscan2
- SCN5A | c.3996G>A p.P1332= (on ENST00000333535 / NM_198056.3; = p.P1331= on NM_000335.5) | Silent (SNP) | VAF 39/201 reads (19%) | catalogued as rs775789293, COSV61127303; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- TAGLN3 | c.252G>A p.K84= | Silent (SNP) | VAF 27/878 reads (3%) | catalogued as COSV56326984; called by muse, mutect2
- TAS2R39 | c.765G>A p.E255= | Silent (SNP) | VAF 165/1146 reads (14%) | catalogued as rs1216625496, COSV101489421; called by muse, mutect2, varscan2
- THSD4 | c.642A>C p.P214= | Silent (SNP) | VAF 64/414 reads (15%) | catalogued as COSV55980219, COSV99967023; called by muse, mutect2, varscan2
- TNXB | c.5604G>T p.V1868= (on ENST00000647633; = p.V1621= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV100926628; called by muse, mutect2, varscan2
- TPRKB | c.270A>G p.S90= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV99721834; called by muse, mutect2, varscan2
- PLXNA4 | c.1372-86990G>C | Intron (SNP) | VAF 43/254 reads (17%) | catalogued as COSV100326939; called by muse, mutect2, varscan2
- PML | c.1710+695G>A | Intron (SNP) | VAF 52/616 reads (8%) | catalogued as rs1242294995, COSV51444676; called by muse, mutect2
- TRIM25 | c.*2C>T | 3'UTR (SNP) | VAF 10/116 reads (9%) | catalogued as COSV100381141; called by muse, mutect2
